CGCI case BLGSP-71-30-00780 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59772983-7323-4729-93b6-0236dcfa8cc7

Demographics
Sex at birth: male; Age at index: 63 years; Vital status: Dead; Days to death: 106 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt-like lymphoma: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 63.0 years (23,023 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 98 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Other; Sites of involvement: Appendix / Small intestine.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Axillary; Tumor largest dimension diameter: 10 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate; Initial disease status: Initial Diagnosis; Days to treatment start: 10 days; Days to treatment end: 30 days; Number of cycles: 4; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: IVAC; Days to treatment start: 35 days; Days to treatment end: 48 days; Number of cycles: 2; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: CODOX; Days to treatment start: 35 days; Days to treatment end: 48 days; Number of cycles: 2; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Cytarabine + Doxorubicin + Etoposide + Ifosfamide + Vincristine; Initial disease status: Progressive Disease; Days to treatment start: 35 days; Days to treatment end: 48 days; Number of cycles: 2; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 3.
- Days to follow up: 98 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MIB1 (IHC): Positive.
- MYC other (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 803 [Blood test normal range upper: 210].

Other clinical attributes
- Day 0: Weight: 95.4 kg; Height: 170 cm; BMI: 33.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00780-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00780-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), atypical morphology; Extranodal site involvement: 3; Extranodal involvment other: cecum; Method initial path diagnosis: Other method, specify:; Lymph nodes examined: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 803; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: MIB-1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Cyclophosphamide, Methotrexate; Pharma adjuvant cycles count: 4; Treatment best response: Clinical Progressive Disease.
- Treatments, Treatment 2: Therapy regimen: Progression after initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: CODOX/IVAC (modified Magrath protocol IVAC without cyclophosphamide); Pharma adjuvant cycles count: 2.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00780-01A-01E-0001-01:
- % tumour: 95
